Somatic mutation profile of tumor specimen TARGET-10-PARJNL-09A (aliquot TARGET-10-PARJNL-09A-01D) from TARGET case TARGET-10-PARJNL, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.0 years (3,655 days).
Specimen TARGET-10-PARJNL-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a6144073-99c0-4be0-8f2e-131f0ee26c00.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARJNL-10A (Blood Derived Normal), aliquot TARGET-10-PARJNL-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d7178035-f5d8-4073-a003-383af0708a26

The open-access MAF lists 22 somatic variants for this specimen: 16 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 3, Intron 1, 5'UTR 1, Splice Region 1, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CRLF2 | c.695T>G p.F232C | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as rs1057519743, COSV67493408; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NEXMIF | c.1441C>T p.R481* | Nonsense Mutation (SNP) | VAF 58/112 reads (52%) | catalogued as rs886041701, COSV50111243; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FCRL5 | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as rs770079990, COSV100708505; called by muse, mutect2, varscan2
- HS6ST1 | c.1088G>A p.R363Q | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); catalogued as rs1177592856; called by muse, mutect2
- ITGB3BP | c.139C>T p.P47S | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.692); catalogued as rs771049427; called by muse, mutect2, varscan2
- KRTAP5-3 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs571662260, COSV101294499, COSV68790920; called by muse, mutect2, varscan2
- LRRC8A | c.625G>A p.V209M | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs753358771; called by muse, mutect2, varscan2
- MANEA | c.157A>G p.I53V | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs757287638; called by muse, mutect2, varscan2
- TENM3 | c.6511A>C p.T2171P | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as COSV101305302; called by muse, mutect2, varscan2
- CR1 | c.471A>T p.E157D | Missense Mutation (SNP) | VAF 73/219 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- DLC1 | c.3008A>T p.H1003L (on ENST00000276297 / NM_001348081.2; = p.H566L on NM_006094.5) | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- JMJD1C | c.4899A>C p.E1633D | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- KCND3 | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- KCNQ2 | c.400A>G p.I134V | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- XIRP2 | c.983A>C p.K328T (on ENST00000628543; = p.K503T on NM_152381.6) | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- ZFPM1 | c.1041C>T p.S347= | Splice Region (SNP) | VAF 7/48 reads (15%) | called by muse, mutect2, varscan2
- KIF17 | c.1338C>T p.D446= | Silent (SNP) | VAF 17/35 reads (49%) | catalogued as rs765789636; called by muse, mutect2, varscan2
- SHISA6 | c.867G>A p.S289= (on ENST00000409168 / NM_001173461.1; = p.S340= on NM_207386.4) | Silent (SNP) | VAF 37/92 reads (40%) | catalogued as rs377388134; called by muse, mutect2, varscan2
- ZFHX4 | c.8049G>T p.L2683= | Silent (SNP) | VAF 59/117 reads (50%) | called by muse, mutect2, varscan2
- AC078899.1 | n.955C>T | RNA (SNP) | VAF 52/130 reads (40%) | called by muse, mutect2, varscan2
- CD14 | c.-21G>C | 5'UTR (SNP) | VAF 30/87 reads (34%) | called by muse, mutect2, varscan2
- OBSCN | c.18662-2662C>T | Intron (SNP) | VAF 6/60 reads (10%) | catalogued as rs867970204, COSV52778041; called by muse, mutect2
